Somatic mutation profile of tumor specimen 0E1AEG from CCDI case PBCVBT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E1AEG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5dc6a92-9bdf-471c-a63f-990a6ec78d27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1AFX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4e0557c-cd3a-410f-b87b-aefd90eb58ea

The open-access MAF lists 642 somatic variants for this specimen: 365 protein-altering or splice-affecting, 179 silent, 98 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 337, Silent 179, Intron 60, 3'UTR 19, Nonsense Mutation 17, 5'UTR 11, Splice Region 9, RNA 4, 5'Flank 3, Splice Site 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO7A | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs111033174, CM050717, COSV68683457; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 152/330 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 135/301 reads (45%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, varscan2
- AC139530.2 | c.573G>A p.T191= | Splice Region (SNP) | VAF 74/181 reads (41%) | catalogued as rs376592800; called by muse, varscan2
- ACTL10 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 109/220 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs983334606; called by muse, varscan2
- ACTL9 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 74/78 reads (95%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as rs1555753460; called by muse, varscan2
- ACTR3B | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 142/302 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); catalogued as COSV55447834; called by muse, varscan2
- ADAMTSL3 | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 142/436 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142860011, COSV54445737; called by muse, varscan2
- ADGRB1 | c.4417C>T p.R1473W | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs961477011, COSV60091791; called by muse, varscan2
- AKAP12 | c.1880C>T p.S627L | Missense Mutation (SNP) | VAF 225/508 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs761711528, COSV99484400; called by muse, varscan2
- AKAP6 | c.6203C>T p.S2068L | Missense Mutation (SNP) | VAF 101/367 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772533351, COSV55205772; called by muse, varscan2
- ANKRD11 | c.5576C>T p.S1859L | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs767688937, COSV56355898; called by muse, varscan2
- ANKRD28 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 166/473 reads (35%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.477); catalogued as rs750556295; called by muse, varscan2
- ANKS3 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.092); catalogued as rs764558382; called by muse, varscan2
- ARFGEF2 | c.4715C>T p.T1572M | Missense Mutation (SNP) | VAF 133/641 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs766756267; called by muse, varscan2
- ARFGEF3 | c.1613C>T p.S538L | Missense Mutation (SNP) | VAF 186/434 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.158); catalogued as rs373609636, COSV52471669; called by muse, varscan2
- ARFGEF3 | c.3592C>T p.R1198W | Missense Mutation (SNP) | VAF 93/527 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1482571015, COSV52461268; called by muse, varscan2
- ARHGAP23 | c.2585C>T p.A862V | Missense Mutation (SNP) | VAF 132/448 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as rs761422042; called by muse, varscan2
- ARHGEF17 | c.4061C>T p.P1354L | Missense Mutation (SNP) | VAF 98/318 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.207); catalogued as rs764876469; called by muse, varscan2
- ATP13A2 | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 106/252 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1173245543; called by muse, varscan2
- ATP13A2 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 110/278 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs764344537; called by muse, varscan2
- ATP8B2 | c.3397C>T p.R1133C (on ENST00000672630; = p.R1100C on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 127/230 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs750885538; called by muse, varscan2
- AXL | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 132/223 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56574964; called by muse, varscan2
- BAX | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 170/282 reads (60%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.65); catalogued as rs369660551; called by muse, varscan2
- BBOX1 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 184/555 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs778849057; called by muse, varscan2
- BEND3 | c.1775G>A p.R592H | Missense Mutation (SNP) | VAF 72/357 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as rs782148186; called by muse, varscan2
- BLVRA | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 196/420 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755595790, COSV55512584; called by muse, varscan2
- BRSK2 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 70/234 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs778370045; called by muse, varscan2
- C2orf16 | c.2938C>T p.R980C | Missense Mutation (SNP) | VAF 185/394 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs1159281670, COSV62677328, COSV99051903; called by muse, varscan2
- CACNA1C | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 128/142 reads (90%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.353); catalogued as rs773211348; ClinVar: uncertain significance; called by muse, varscan2
- CAMTA2 | c.2173C>T p.R725C | Missense Mutation (SNP) | VAF 202/464 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs965310553; called by muse, varscan2
- CAPN13 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 142/350 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.537); catalogued as rs369616026; called by muse, varscan2
- CAPS2 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 278/602 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs562989650, COSV60824200; called by muse, varscan2
- CASKIN1 | c.3091C>T p.R1031C | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs575231658; called by muse, varscan2
- CCDC166 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 63/153 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.38); catalogued as rs1415879596; called by muse, varscan2
- CCDC68 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 248/392 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs771391383, COSV61604209; called by muse, varscan2
- CCDC80 | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 374/750 reads (50%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs747085670, COSV99244316; called by muse, varscan2
- CCDC80 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 212/438 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs771380755, COSV52814709; called by muse, varscan2
- CCNP | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 80/252 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.925); catalogued as rs774696618; called by muse, varscan2
- CCNP | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 124/200 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1443700611; called by muse, varscan2
- CCR8 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 116/276 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs199538266; called by muse, varscan2
- CD248 | c.859G>A p.G287S | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs374192163; called by muse, varscan2
- CD44 | c.1439C>T p.T480M | Missense Mutation (SNP) | VAF 246/430 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs367650491; called by muse, varscan2
- CD48 | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 221/557 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs933227640, COSV63566085; called by muse, varscan2
- CD83 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 159/181 reads (88%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as rs147342996, COSV64788109; called by muse, varscan2
- CDH1 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 74/188 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); catalogued as rs1375178645; called by muse, varscan2
- CDH23 | c.4274C>T p.A1425V | Missense Mutation (SNP) | VAF 148/308 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs753568239; called by muse, varscan2
- CDKL5 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 147/158 reads (93%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); catalogued as rs867056809, COSV66111162; called by muse, varscan2
- CELF3 | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 100/304 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1219890756, COSV51885144; called by muse, varscan2
- CENPJ | c.3737C>T p.T1246M | Missense Mutation (SNP) | VAF 107/435 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs767833776, COSV55036267; called by muse, varscan2
- CFAP43 | c.3982G>A p.V1328I | Missense Mutation (SNP) | VAF 190/458 reads (41%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs886950253, COSV63852657; called by muse, varscan2
- CHPF | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 90/195 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs145792368; called by muse, varscan2
- CLDN2 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 134/147 reads (91%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.906); catalogued as rs1371738496; called by muse, varscan2
- CLIP2 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 162/338 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs1347480501, COSV99791293; called by muse, varscan2
- CLSTN1 | c.1132G>A p.V378M (on ENST00000377298 / NM_001009566.3; = p.V368M on NM_014944.4) | Missense Mutation (SNP) | VAF 64/306 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs759541267; called by muse, varscan2
- CNN1 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 90/102 reads (88%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs763389217, COSV52947893; called by muse, varscan2
- CNOT1 | c.6488G>A p.R2163Q | Missense Mutation (SNP) | VAF 154/308 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs368556234; called by muse, varscan2
- CNTNAP1 | c.2773C>T p.R925C | Missense Mutation (SNP) | VAF 163/368 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs755673095, COSV99226209; called by muse, varscan2
- CPT1C | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 69/253 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as rs373239966; called by muse, varscan2
- CRELD1 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 156/310 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as rs761961706; called by muse, varscan2
- CRYGA | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 148/296 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as rs779538919, COSV58016411; called by muse, varscan2
- CTNNBL1 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 210/470 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs755636908, COSV63745919; called by muse, varscan2
- CYB5R1 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 68/428 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1246184974, COSV100579471, COSV61852299; called by muse, varscan2
- CYP27C1 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 46/315 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747388358; called by muse, varscan2
- CYP2B6 | c.13G>A p.V5I | Missense Mutation (SNP) | VAF 133/210 reads (63%) | SIFT tolerated (0.41); PolyPhen benign (0.042); catalogued as rs147304516; called by muse, varscan2
- DAGLA | c.2675G>A p.R892H | Missense Mutation (SNP) | VAF 114/180 reads (63%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.021); catalogued as rs146614173; called by muse, varscan2
- DCBLD1 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 120/516 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.23); catalogued as rs1345084436, COSV99757006; called by muse, varscan2
- DCLK1 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 135/510 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs373217123; called by muse, varscan2
- DCST2 | c.697G>A p.V233M | Missense Mutation (SNP) | VAF 212/446 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.306); catalogued as rs373275652; called by muse, varscan2
- DDI1 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 177/212 reads (83%) | catalogued as COSV56369663; called by muse, varscan2
- DENND2B | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT tolerated (0.88); PolyPhen benign (0.017); catalogued as rs760930186; called by muse, varscan2
- DGCR6L | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 108/190 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs758170132, COSV50619638; called by muse, varscan2
- DIS3L2 | c.2371G>A p.V791M | Missense Mutation (SNP) | VAF 74/266 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs374080052; ClinVar: uncertain significance; called by muse, varscan2
- DMXL2 | c.7118C>T p.A2373V | Missense Mutation (SNP) | VAF 142/429 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1555415188; called by muse, varscan2
- DNM1 | c.2188C>T p.R730C | Missense Mutation (SNP) | VAF 112/178 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs10987947; called by muse, varscan2
- DNMT1 | c.3019G>A p.G1007S | Missense Mutation (SNP) | VAF 185/209 reads (89%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.874); catalogued as rs1256073808, COSV61576584; called by muse, varscan2
- DOCK6 | c.1579C>T p.R527W | Missense Mutation (SNP) | VAF 160/169 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs769092830; called by muse, varscan2
- DPCD | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 174/415 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776427309, COSV64509146; called by muse, varscan2
- DPPA2 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 236/538 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1369554028; called by muse, varscan2
- DPY19L2 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 262/484 reads (54%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs569045259; called by muse, varscan2
- DUS3L | c.1090G>A p.V364I | Missense Mutation (SNP) | VAF 124/143 reads (87%) | SIFT tolerated (0.12); PolyPhen benign (0.078); catalogued as rs143475735; called by muse, varscan2
- EEF2KMT | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 88/216 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs760472451; called by muse, varscan2
- EFCAB6 | c.4319G>A p.R1440Q | Missense Mutation (SNP) | VAF 118/287 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53068314; called by muse, varscan2
- EFEMP1 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 120/257 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.029); catalogued as rs373554215; called by muse, varscan2
- EFTUD2 | c.2527G>A p.V843I | Missense Mutation (SNP) | VAF 194/448 reads (43%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.721); catalogued as rs988941371; called by muse, varscan2
- EGFR | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 303/626 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1562756942, COSV51837186; ClinVar: uncertain significance; called by muse, varscan2
- EIF3A | c.3029G>A p.R1010H | Missense Mutation (SNP) | VAF 112/282 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as rs1193642105, COSV64961971; called by muse, varscan2
- ELFN1 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 102/203 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs765480745; called by muse, varscan2
- ELOVL7 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 142/156 reads (91%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1425385292, COSV70917879; called by muse, varscan2
- EML2 | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 103/173 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.277); catalogued as rs866166593; called by muse, varscan2
- EPAS1 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 112/384 reads (29%) | catalogued as COSV55384009; called by muse, varscan2
- EPB41L4B | c.2236C>T p.R746* | Nonsense Mutation (SNP) | VAF 142/262 reads (54%) | catalogued as rs755694840, COSV100775853; called by muse, varscan2
- EPHB2 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 121/260 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as rs201754821; called by muse, varscan2
- EPHB6 | c.2159G>A p.R720Q | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs775131118, COSV63891284; called by muse, varscan2
- ERMARD | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 160/708 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs375856725; called by muse, varscan2
- ERN2 | c.2683C>T p.R895* | Nonsense Mutation (SNP) | VAF 79/187 reads (42%) | catalogued as rs566355568; called by muse, varscan2
- EVPL | c.4348G>A p.E1450K | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV56908161; called by muse, varscan2
- F11R | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 227/424 reads (54%) | catalogued as rs754154040; called by muse, varscan2
- FAAP100 | c.2587G>A p.A863T | Missense Mutation (SNP) | VAF 100/232 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.236); catalogued as rs778557641; called by muse, varscan2
- FAM210A | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 100/413 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs752367715; called by muse, varscan2
- FAM83H | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 56/230 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1267051470; called by muse, varscan2
- FAM89A | c.418G>A p.G140S | Missense Mutation (SNP) | VAF 167/311 reads (54%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as rs769444149, COSV64166705; called by muse, varscan2
- FBXO38 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 390/438 reads (89%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV57026947; called by muse, varscan2
- FBXW11 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 271/289 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1346102267, COSV51605761; called by muse, varscan2
- FCGBP | c.6958G>A p.A2320T | Missense Mutation (SNP) | VAF 54/508 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.526); catalogued as rs200094949; called by muse, varscan2
- FER1L5 | c.3545G>A p.R1182H (on ENST00000623019; = p.R1155H on NM_001293083.2) | Missense Mutation (SNP) | VAF 124/354 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775780731, COSV101208890; called by muse, varscan2
- FLNC | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 101/219 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs962872361, COSV57955594; called by muse, varscan2
- FLRT1 | c.1774C>T p.R592W | Missense Mutation (SNP) | VAF 90/202 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs375487485; called by muse, varscan2
- FRMD5 | c.1225C>T p.R409W | Missense Mutation (SNP) | VAF 131/356 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs751630464, COSV68724256; called by muse, varscan2
- FSTL1 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 182/448 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.409); catalogued as rs150197564; called by muse, varscan2
- FYN | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 260/614 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.049); catalogued as rs1359936085, COSV57613493; called by muse, varscan2
- GAK | c.1957G>A p.G653S | Missense Mutation (SNP) | VAF 107/122 reads (88%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); catalogued as rs547795406, COSV100033308, COSV100033634; called by muse, varscan2
- GDF11 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 114/200 reads (57%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs1177150502, COSV57689570, COSV57690350; called by muse, varscan2
- GNAS | c.7G>A p.V3M | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs781303953, COSV58333086; called by muse, varscan2
- GOLGA6L2 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 106/378 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.968); catalogued as rs745978724; called by muse, varscan2
- H1-8 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 138/369 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs748783783; called by muse, varscan2
- HCN4 | c.2716G>A p.G906R | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.06); catalogued as rs373572497; ClinVar: uncertain significance; called by muse, varscan2
- HDHD3 | c.50C>T p.T17M | Missense Mutation (SNP) | VAF 183/303 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746796130; called by muse, varscan2
- HERC2 | c.13235G>A p.R4412H | Missense Mutation (SNP) | VAF 117/359 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs773154583; called by muse, varscan2
- IFT172 | c.5005G>A p.A1669T | Missense Mutation (SNP) | VAF 160/283 reads (57%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs146575848; called by muse, varscan2
- IGSF10 | c.1477G>A p.V493I | Missense Mutation (SNP) | VAF 216/516 reads (42%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs370165815; called by muse, varscan2
- IKZF1 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 34/310 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as rs1446212014, COSV58783463, COSV58786626; called by muse, varscan2
- ILDR2 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1377515280, COSV54829340; called by muse, varscan2
- INO80C | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 218/497 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs753851419; called by muse, varscan2
- IPP | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 177/406 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775498465; called by muse, varscan2
- ITGB3 | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 88/470 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1199275720, CM108897; called by muse, varscan2
- ITGB4 | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 121/268 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs531073554, COSV52323207; called by muse, varscan2
- ITPR1 | c.2782G>A p.V928M (on ENST00000354582; = p.V913M on NM_002222.7) | Missense Mutation (SNP) | VAF 238/512 reads (46%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as rs751172849, COSV56966167; called by muse, varscan2
- JAG2 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 90/142 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1448629549; called by muse, varscan2
- KATNA1 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 300/650 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs748635170, COSV100167580; called by muse, varscan2
- KCNQ2 | c.2197G>A p.V733M (on ENST00000359125 / NM_172107.4; = p.V705M on NM_004518.6) | Missense Mutation (SNP) | VAF 86/180 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs756563523; called by muse, varscan2
- KCTD19 | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 106/222 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs556759064; called by muse, varscan2
- KEAP1 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.234); catalogued as rs773315433; called by muse, varscan2
- KIAA0100 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 172/412 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1436708679, COSV66493476; called by muse, varscan2
- KIAA0930 | c.949G>A p.A317T (on ENST00000336156 / NM_001009880.2; = p.A322T on NM_015264.2) | Missense Mutation (SNP) | VAF 184/390 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs745738357; called by muse, varscan2
- KLHDC1 | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as rs772110151; called by muse, varscan2
- KRT2 | c.588G>A p.V196= | Splice Region (SNP) | VAF 86/254 reads (34%) | catalogued as rs1565640389; called by muse, varscan2
- KRT82 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 115/338 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs769318337; called by muse, varscan2
- LHX4 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 150/408 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as rs145933198, COSV55373655, COSV55378142; ClinVar: uncertain significance; called by muse, varscan2
- LIMK2 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 127/248 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs370892426; called by muse, varscan2
- LMTK3 | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.531); catalogued as rs910405622; called by muse, varscan2
- LOXL1 | c.1541C>T p.A514V | Missense Mutation (SNP) | VAF 96/200 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745893746; called by muse, varscan2
- LRFN4 | c.946G>A p.G316S | Missense Mutation (SNP) | VAF 78/122 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs781763774; called by muse, varscan2
- LRRC37A3 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 144/490 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs148778730; called by muse, varscan2
- LRRC8E | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs1008478167; called by muse, varscan2
- LRRK1 | c.4270G>A p.V1424M | Missense Mutation (SNP) | VAF 133/256 reads (52%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); catalogued as rs767219901, COSV52609803; called by muse, varscan2
- LTN1 | c.5122C>T p.R1708C | Missense Mutation (SNP) | VAF 98/380 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773146764; called by muse, varscan2
- LYG2 | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 92/234 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs757888913, COSV60715574; called by muse, varscan2
- LZTR1 | c.1609C>T p.R537W | Missense Mutation (SNP) | VAF 116/225 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs754507552; called by muse, varscan2
- MAPK8IP1 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 66/235 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.629); catalogued as rs572233757, COSV53798101, COSV99571685; called by muse, varscan2
- MARCHF6 | c.2677C>T p.R893W | Missense Mutation (SNP) | VAF 158/424 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs142412317, COSV99929404; called by muse, varscan2
- MCM3AP | c.2042C>T p.A681V | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1186975092; called by muse, varscan2
- MED12 | c.4664C>T p.T1555M | Missense Mutation (SNP) | VAF 146/156 reads (94%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as rs1436223575; called by muse, varscan2
- MFSD3 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 95/233 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs191044206; called by muse, varscan2
- MGAT3 | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1395707836, COSV57866467; called by muse, varscan2
- MICB | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs775923426; called by muse, varscan2
- MPPED1 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 150/315 reads (48%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.453); catalogued as rs771149146; called by muse, varscan2
- MSLN | c.1679C>T p.A560V (on ENST00000382862 / NM_013404.4; = p.A552V on NM_005823.6) | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as rs759470705; called by muse, varscan2
- MTMR3 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 256/638 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.124); catalogued as rs780839383, COSV100071535; called by muse, varscan2
- MTRR | c.349C>T p.R117W (on ENST00000264668; = p.R90W on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 190/512 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.061); catalogued as rs773984668, COSV52945478; ClinVar: uncertain significance; called by muse, varscan2
- MX2 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 98/190 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as rs749482420, COSV58098973; called by muse, varscan2
- MYBPC1 | c.1939G>A p.G647R (on ENST00000550270 / NM_206820.2; = p.G672R on NM_002465.4) | Missense Mutation (SNP) | VAF 183/327 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767366434, COSV62255917; called by muse, varscan2
- MYCBPAP | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 176/405 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750540313, COSV60405361; called by muse, varscan2
- MYH3 | c.3997G>A p.A1333T | Missense Mutation (SNP) | VAF 235/517 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs200734527, COSV56863991, COSV56865662; called by muse, varscan2
- MYLK | c.5041G>A p.D1681N | Missense Mutation (SNP) | VAF 240/510 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs150392984; called by muse, varscan2
- MYO15B | c.8062C>T p.R2688W | Missense Mutation (SNP) | VAF 98/215 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as rs768219032; called by muse, varscan2
- NAGLU | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs753409259; called by muse, varscan2
- NBEA | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 146/554 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59781640; called by muse, varscan2
- NCOR1 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 144/572 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs753080572; called by muse, varscan2
- NCOR2 | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 126/364 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369121940; called by muse, varscan2
- NDC80 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 92/100 reads (92%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1197300304; called by muse, varscan2
- NFE2 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 120/215 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs368351144, COSV56456526; called by muse, varscan2
- NISCH | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 156/324 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs199663460, COSV100617527; called by muse, varscan2
- OLFML2A | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775121644, COSV56583722; called by muse, varscan2
- ORMDL1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 224/520 reads (43%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.988); catalogued as rs774962765; called by muse, varscan2
- OTOG | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 114/387 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as rs909124808; called by muse, varscan2
- OXSR1 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 170/376 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.154); catalogued as rs191643511; called by muse, varscan2
- PADI1 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 246/454 reads (54%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs760951556, COSV64938943; called by muse, varscan2
- PCDHA13 | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 120/138 reads (87%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.034); catalogued as COSV56537515; called by muse, varscan2
- PDZD2 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 84/292 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs749035781, COSV56851838; called by muse, varscan2
- PGAM4 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 156/404 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs782273833, COSV100430058; called by muse, varscan2
- PGAM5 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 108/226 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs780048914; called by muse, varscan2
- PHLPP2 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 176/337 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374229954; called by muse, varscan2
- PI4K2B | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 272/290 reads (94%) | catalogued as rs771687570; called by muse, varscan2
- PIK3CG | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 144/300 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as rs778022267, COSV63248617; called by muse, varscan2
- PIK3R3 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 358/728 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs775105727; called by muse, varscan2
- PIK3R5 | c.2281C>T p.R761W | Missense Mutation (SNP) | VAF 139/318 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs201299435, COSV52656247; ClinVar: uncertain significance; called by muse, varscan2
- PKD1L1 | c.1891G>A p.V631I | Missense Mutation (SNP) | VAF 196/444 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.061); catalogued as rs756434620; called by muse, varscan2
- PLEKHA4 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 122/198 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as rs778302948; called by muse, varscan2
- PLK3 | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.818); catalogued as rs146191329; called by muse, varscan2
- PLOD1 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 209/398 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.614); catalogued as rs771186398; ClinVar: uncertain significance; called by muse, varscan2
- PLXNA1 | c.2219G>A p.R740H | Missense Mutation (SNP) | VAF 102/250 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1340705391, COSV52532778; called by muse, varscan2
- PLXNB2 | c.3742C>T p.R1248C | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1452915116, COSV63784460; called by muse, varscan2
- POLE | c.2461C>T p.R821C | Missense Mutation (SNP) | VAF 110/388 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1483635586, COSV57674926; ClinVar: uncertain significance; called by muse, varscan2
- POLG | c.1850G>A p.R617H | Missense Mutation (SNP) | VAF 114/207 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as rs779961986; ClinVar: uncertain significance / benign; called by muse, varscan2
- POLH | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 190/210 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs765084986; called by muse, varscan2
- PPP1R9A | c.28C>T p.R10* | Nonsense Mutation (SNP) | VAF 138/670 reads (21%) | catalogued as rs763421355; called by muse, varscan2
- PPP2R3B | c.1085+8C>T | Splice Region (SNP) | VAF 83/188 reads (44%) | catalogued as rs760330110; called by muse, varscan2
- PPP5C | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 80/247 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as rs768868888; called by muse, varscan2
- PRDM9 | c.2474C>T p.T825I | Missense Mutation (SNP) | VAF 130/670 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as rs771865179; called by muse, varscan2
- PRKCE | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 116/295 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759149125; called by muse, varscan2
- PRPF6 | c.2023G>A p.A675T | Missense Mutation (SNP) | VAF 93/226 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.887); catalogued as COSV99413148; called by muse, varscan2
- PRRC2B | c.5771C>T p.P1924L | Missense Mutation (SNP) | VAF 75/253 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs767319599; called by muse, varscan2
- PRSS21 | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 86/138 reads (62%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as rs1281243479; called by muse, varscan2
- PSKH1 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 111/268 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.249); catalogued as rs1000942376, COSV52123429; called by muse, varscan2
- PSMD3 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 129/235 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs767947232, COSV52857123, COSV99227575; called by muse, varscan2
- PSPN | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs751627297; called by muse, varscan2
- PTGDS | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); catalogued as rs778530805; called by muse, varscan2
- PTPN13 | c.7234A>G p.I2412V (on ENST00000411767 / NM_080683.3; = p.I2393V on NM_006264.3) | Missense Mutation (SNP) | VAF 224/480 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs768189344; called by muse, varscan2
- PTPRE | c.1386G>A p.P462= | Splice Region (SNP) | VAF 86/209 reads (41%) | catalogued as rs143511195, COSV54558883; called by muse, varscan2
- PTPRU | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 226/452 reads (50%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as rs775231191, COSV100111452; called by muse, varscan2
- PYGB | c.1891G>A p.V631I | Missense Mutation (SNP) | VAF 89/491 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as rs756993956; called by muse, varscan2
- QRICH1 | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.167); catalogued as rs1338618407, COSV62615296; called by muse, varscan2
- RANBP9 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 246/284 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368142762; called by muse, varscan2
- RAPGEFL1 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 184/406 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751331577, COSV99229087; called by muse, varscan2
- RBM14 | c.1843C>T p.R615C | Missense Mutation (SNP) | VAF 131/403 reads (33%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs768155048; called by muse, varscan2
- RBM23 | c.488G>A p.R163H (on ENST00000359890 / NM_001077351.2; = p.R147H on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/348 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs779737231, COSV57126821; called by muse, varscan2
- RBM6 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 183/382 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs749835913; called by muse, varscan2
- RECQL5 | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 116/312 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs752969417; called by muse, varscan2
- RERE | c.2339C>T p.T780M | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.104); catalogued as rs571434485; called by muse, varscan2
- RHBDF1 | c.1894-4G>A | Splice Region (SNP) | VAF 50/138 reads (36%) | catalogued as rs374612033; called by muse, varscan2
- RIMBP2 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 102/346 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.175); catalogued as rs1370311081; called by muse, varscan2
- RIMS2 | c.1523G>A p.R508H (on ENST00000666250 / NM_001348490.2; = p.R316H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 136/704 reads (19%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV51669990; called by muse, varscan2
- RIMS2 | c.3254G>A p.R1085H (on ENST00000666250 / NM_001348490.2; = p.R893H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 146/383 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.125); catalogued as rs377554442; called by muse, varscan2
- RND2 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 138/334 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs773244091; called by muse, varscan2
- RNF169 | c.1012G>A p.V338I | Missense Mutation (SNP) | VAF 358/610 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs747686347; called by muse, varscan2
- RRP1B | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 68/213 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as rs754566182; called by muse, varscan2
- RRP7A | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 44/290 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs142219748; called by muse, varscan2
- RTEL1 | c.3508C>T p.R1170W | Missense Mutation (SNP) | VAF 62/225 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs773894104; called by muse, varscan2
- RUBCN | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 132/291 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs753948060, COSV56363933, COSV99584320; called by muse, varscan2
- SALL4 | c.2129C>T p.T710M | Missense Mutation (SNP) | VAF 157/334 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs761020459, COSV53851667; called by muse, varscan2
- SDCBP2 | c.473G>A p.R158H (on ENST00000339987 / NM_001199784.1; = p.R73H on NM_015685.5) | Missense Mutation (SNP) | VAF 68/294 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs747790242, COSV60588347; called by muse, varscan2
- SEC14L5 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs544613783; called by muse, varscan2
- SETD2 | c.5636G>A p.R1879H | Missense Mutation (SNP) | VAF 251/661 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1357325164, COSV100340114; called by muse, varscan2
- SLC25A25 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 150/251 reads (60%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs772416779, COSV66086197; called by muse, varscan2
- SLC30A9 | c.1666C>T p.R556* | Nonsense Mutation (SNP) | VAF 288/616 reads (47%) | catalogued as COSV52556703; called by muse, varscan2
- SLC45A4 | c.1768G>A p.V590I (on ENST00000517878 / NM_001286646.2; = p.V539I on NM_001080431.2) | Missense Mutation (SNP) | VAF 76/330 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139874236; called by muse, varscan2
- SLC7A11 | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 209/456 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs751679927; called by muse, varscan2
- SLIT2 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 270/305 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs756812021, COSV56571632; called by muse, varscan2
- SLITRK5 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 159/184 reads (86%) | SIFT tolerated (0.66); PolyPhen benign (0.219); catalogued as rs368879058; called by muse, varscan2
- SMAD5 | c.1249G>A p.V417I | Missense Mutation (SNP) | VAF 170/188 reads (90%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.713); catalogued as rs991396564, COSV101548126; called by muse, varscan2
- SMAD6 | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 103/200 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs772926628; called by muse, varscan2
- SPEN | c.7025G>A p.R2342Q | Missense Mutation (SNP) | VAF 202/400 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as rs747967254, COSV65368923; called by muse, varscan2
- SPHK2 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 32/154 reads (21%) | catalogued as rs1260382422; called by muse, varscan2
- SRMS | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 150/318 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779008500; called by muse, varscan2
- STS | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 116/128 reads (91%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.453); catalogued as rs909476411; called by muse, varscan2
- STX4 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as rs376316073; called by muse, varscan2
- SV2A | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 196/533 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.878); catalogued as rs782027117, COSV64964160; called by muse, varscan2
- TACC2 | c.5380G>A p.V1794I | Missense Mutation (SNP) | VAF 120/253 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs777458270; called by muse, varscan2
- TECPR1 | c.1421C>T p.T474M | Missense Mutation (SNP) | VAF 72/220 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.063); catalogued as rs574909069; called by muse, varscan2
- TEKT4 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 152/272 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs371847557; called by muse, varscan2
- TENM3 | c.61C>T p.R21W | Missense Mutation (SNP) | VAF 112/332 reads (34%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.875); catalogued as rs373428556, COSV69316127; called by muse, varscan2
- TKTL2 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 93/253 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); catalogued as rs913908509, COSV54917411; called by muse, varscan2
- TLE1 | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 216/346 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1485917444; called by muse, varscan2
- TLR5 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 198/419 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as rs746631286, COSV60559537; called by muse, varscan2
- TMPRSS3 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs139865555; ClinVar: uncertain significance; called by muse, varscan2
- TMX3 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 376/636 reads (59%) | catalogued as rs376484673; called by muse, varscan2
- TNFRSF21 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 286/317 reads (90%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.626); catalogued as rs143678843; called by muse, varscan2
- TNRC18 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 90/191 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1332775837; called by muse, varscan2
- TOP3A | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 131/303 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as rs778504793, COSV58176447; called by muse, varscan2
- TRABD2A | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 160/402 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1249973107; called by muse, varscan2
- TRANK1 | c.4288G>A p.V1430M | Missense Mutation (SNP) | VAF 104/255 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777724026, COSV57153436; called by muse, varscan2
- TRPM2 | c.4000C>T p.R1334C | Missense Mutation (SNP) | VAF 78/228 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as rs753208177, COSV55968301; called by muse, varscan2
- TRPM5 | c.3382G>A p.G1128S | Missense Mutation (SNP) | VAF 67/226 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs757453266, COSV50177911; called by muse, varscan2
- TRPM6 | c.865G>A p.V289M | Missense Mutation (SNP) | VAF 95/382 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs182530243; called by muse, varscan2
- TTN | c.100337C>T p.T33446M (on ENST00000591111; = p.T26022M on NM_003319.4) | Missense Mutation (SNP) | VAF 162/368 reads (44%) | PolyPhen probably damaging (0.916); catalogued as rs397517795, COSV60163594; ClinVar: uncertain significance; called by muse, varscan2
- TUBAL3 | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 85/525 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs782349788, COSV100990527; called by muse, varscan2
- TUBB4B | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 92/319 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.956); catalogued as rs1207111232; called by muse, varscan2
- UBL7 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.283); catalogued as rs1238735233; called by muse, varscan2
- UBR1 | c.3848C>T p.S1283L | Missense Mutation (SNP) | VAF 164/512 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs561720791, COSV99317790; called by muse, varscan2
- UNC119 | c.437+1G>A p.X146_splice | Splice Site (SNP) | VAF 118/258 reads (46%) | catalogued as rs761866874; called by muse, varscan2
- UNKL | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 74/136 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs866604381; called by muse, varscan2
- USP49 | c.644C>T p.T215M | Missense Mutation (SNP) | VAF 84/88 reads (95%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1286364886, COSV51894782; called by muse, varscan2
- UVRAG | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 282/471 reads (60%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.872); catalogued as rs148858611; called by muse, varscan2
- VWF | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 87/95 reads (92%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.995); catalogued as COSV54623805; called by muse, varscan2
- WDR62 | c.3544G>A p.V1182M | Missense Mutation (SNP) | VAF 120/192 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs587784557; ClinVar: uncertain significance; called by muse, varscan2
- WDR81 | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 78/164 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as rs775240530; called by muse, varscan2
- ZBTB21 | c.2953C>T p.P985S | Missense Mutation (SNP) | VAF 162/284 reads (57%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs1390609419; called by muse, varscan2
- ZBTB7B | c.1429G>A p.A477T (on ENST00000292176; = p.A511T on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/213 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs145857967; called by muse, varscan2
- ZCCHC8 | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 220/424 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs776584825, COSV100288444; called by muse, varscan2
- ZDHHC14 | c.1124C>T p.T375M | Missense Mutation (SNP) | VAF 162/356 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.732); catalogued as rs370693708; called by muse, varscan2
- ZNF106 | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 269/481 reads (56%) | catalogued as rs1436705939, COSV55523050; called by muse, varscan2
- ZNF335 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 222/496 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs754669594, COSV59815798; called by muse, varscan2
- ZNF438 | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 218/457 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as rs201579158, COSV59200828; called by muse, varscan2
- ZNF451 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 384/427 reads (90%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1335357514; called by muse, varscan2
- ZNF536 | c.1666G>A p.G556R | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs777668151, COSV62821271; called by muse, varscan2
- ZNF549 | c.746G>A p.R249H (on ENST00000376233 / NM_001199295.2; = p.R236H on NM_153263.2) | Missense Mutation (SNP) | VAF 78/352 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs200419451, COSV99558447; called by muse, varscan2
- ZNF565 | c.151G>A p.V51M (on ENST00000355114; = p.V11M on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 178/318 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs766175480, COSV100411896; called by muse, varscan2
- ZNF697 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 175/344 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs768520493, COSV70284232; called by muse, varscan2
- ZNF793 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs759077203, COSV71325173; called by muse, varscan2
- ZNFX1 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 192/418 reads (46%) | catalogued as rs1009014344, COSV65574516; called by muse, varscan2
- ZSCAN26 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 260/298 reads (87%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as rs749299020; called by muse, varscan2
- ADAM2 | c.1987C>A p.P663T | Missense Mutation (SNP) | VAF 196/388 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.421); called by muse, varscan2
- ADGRG4 | c.397T>A p.L133I | Missense Mutation (SNP) | VAF 198/216 reads (92%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, varscan2
- ALG13 | c.2973+8C>T | Splice Region (SNP) | VAF 160/175 reads (91%) | called by muse, varscan2
- ARVCF | c.2594C>A p.P865H | Missense Mutation (SNP) | VAF 162/406 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.281); called by muse, varscan2
- BANP | c.736C>T p.R246C (on ENST00000286122; = p.R215C on NM_017869.4) | Missense Mutation (SNP) | VAF 77/156 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, varscan2
- BCL11A | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 290/580 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, varscan2
- BCL6 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 335/685 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- BRD3 | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 104/182 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, varscan2
- C10orf71 | c.3724G>A p.V1242M | Missense Mutation (SNP) | VAF 132/272 reads (49%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.672); called by muse, varscan2
- CCDC130 | c.712+5G>A | Splice Region (SNP) | VAF 60/200 reads (30%) | called by muse, varscan2
- CCDC177 | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.25); called by muse, varscan2
- CFAP47 | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 113/123 reads (92%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.205); called by muse, varscan2
- CLASRP | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.706); called by muse, varscan2
- COL17A1 | c.3277C>T p.R1093W | Missense Mutation (SNP) | VAF 104/244 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- COL6A5 | c.3227C>G p.S1076C | Missense Mutation (SNP) | VAF 110/452 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); called by muse, varscan2
- DAAM2 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 174/207 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- DCHS1 | c.5669T>C p.V1890A | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, varscan2
- DCLRE1B | c.794A>G p.H265R | Missense Mutation (SNP) | VAF 219/426 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.372); called by muse, varscan2
- DNAH1 | c.8366G>A p.C2789Y | Missense Mutation (SNP) | VAF 70/324 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, varscan2
- DUS3L | c.566A>G p.Q189R | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, varscan2
- EDC4 | c.3004+6C>A | Splice Region (SNP) | VAF 104/220 reads (47%) | called by muse, varscan2
- EMX1 | c.377C>A p.P126H | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.26); called by muse, varscan2
- FAM120B | c.1711G>A p.V571I | Missense Mutation (SNP) | VAF 233/500 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.034); called by muse, varscan2
- FASN | c.7054C>T p.R2352W | Missense Mutation (SNP) | VAF 128/299 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FSD2 | c.1998G>A p.R666= | Splice Region (SNP) | VAF 50/263 reads (19%) | called by muse, varscan2
- FZD10 | c.1726C>T p.Q576* | Nonsense Mutation (SNP) | VAF 68/242 reads (28%) | called by muse, varscan2
- GPR45 | c.712C>A p.L238M | Missense Mutation (SNP) | VAF 128/292 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, varscan2
- GRM8 | c.359T>A p.V120E | Missense Mutation (SNP) | VAF 292/641 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- GTF3C4 | c.2213T>C p.M738T | Missense Mutation (SNP) | VAF 296/485 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- HIRA | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 168/350 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- KDM5C | c.947A>G p.H316R | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.171); called by muse, varscan2
- KIF19 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 134/288 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- KIF7 | c.1339G>A p.V447I | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.442); called by muse, varscan2
- LHX2 | c.325C>G p.R109G | Missense Mutation (SNP) | VAF 130/224 reads (58%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.873); called by muse, varscan2
- LRP1B | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 91/599 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, varscan2
- LRRC24 | c.1198G>T p.G400C | Missense Mutation (SNP) | VAF 78/170 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- MPST | c.26C>T p.A9V (on ENST00000341116 / NM_001369904.2; = p.A29V on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/248 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.134); called by muse, varscan2
- MROH2B | c.3872A>G p.K1291R | Missense Mutation (SNP) | VAF 208/422 reads (49%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.723); called by muse, varscan2
- MUC4 | c.16069G>A p.E5357K (on ENST00000463781 / NM_018406.7; = p.E1121K on NM_004532.6) | Missense Mutation (SNP) | VAF 205/658 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); called by muse, varscan2
- MYO18B | c.2482G>T p.A828S | Missense Mutation (SNP) | VAF 132/255 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, varscan2
- NAA25 | c.1467G>A p.W489* | Nonsense Mutation (SNP) | VAF 187/339 reads (55%) | called by muse, varscan2
- OR2D2 | c.12A>G p.I4M | Missense Mutation (SNP) | VAF 226/435 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, varscan2
- OSR2 | c.578C>T p.T193I | Missense Mutation (SNP) | VAF 156/402 reads (39%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.842); called by muse, varscan2
- OTUD7A | c.2300G>A p.G767D (on ENST00000307050 / NM_001382637.1; = p.G760D on NM_130901.3) | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.26); called by muse, varscan2
- PDGFRA | c.1016T>C p.V339A | Missense Mutation (SNP) | VAF 2423/2593 reads (93%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, varscan2
- PER2 | c.1733C>T p.T578I | Missense Mutation (SNP) | VAF 52/238 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, varscan2
- PIK3CB | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 142/338 reads (42%) | called by muse, varscan2
- PLXNB1 | c.4487G>A p.G1496D | Missense Mutation (SNP) | VAF 150/296 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, varscan2
- PPEF1 | c.1933A>G p.M645V | Missense Mutation (SNP) | VAF 93/112 reads (83%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, varscan2
- PPM1H | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 107/190 reads (56%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.608); called by muse, varscan2
- PTGDR2 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 90/178 reads (51%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, varscan2
- RARB | c.272G>A p.C91Y (on ENST00000383772 / NM_001290216.2; = p.C84Y on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 208/500 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, varscan2
- RBBP9 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 298/555 reads (54%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.703); called by muse, varscan2
- RBM19 | c.1874C>T p.A625V | Missense Mutation (SNP) | VAF 178/308 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, varscan2
- S100A7 | c.149A>G p.K50R | Missense Mutation (SNP) | VAF 258/542 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, varscan2
- SERPINA6 | c.146G>T p.S49I | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.251); called by muse, varscan2
- SLC35A1 | c.328A>C p.S110R | Missense Mutation (SNP) | VAF 265/643 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- SLC35A2 | c.725G>A p.G242D | Missense Mutation (SNP) | VAF 109/122 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- SLF2 | c.251C>T p.T84I | Missense Mutation (SNP) | VAF 212/544 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.136); called by muse, varscan2
- SMG1 | c.6466+2T>C p.X2156_splice | Splice Site (SNP) | VAF 221/436 reads (51%) | called by muse, varscan2
- SNX7 | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 234/622 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, varscan2
- SOWAHA | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 176/190 reads (93%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, varscan2
- SPTBN5 | c.6035C>T p.A2012V | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.12); called by muse, varscan2
- SRGAP2B | c.1210G>T p.E404* (on ENST00000612199 / NM_001366280.1; = p.E405* on NM_001271870.3) | Nonsense Mutation (SNP) | VAF 248/885 reads (28%) | called by muse, varscan2
- STMN1 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 204/496 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); called by muse, varscan2
- STXBP1 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 156/517 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.125); called by muse, varscan2
- SYNE1 | c.21842C>T p.T7281I (on ENST00000367255 / NM_182961.4; = p.T7210I on NM_033071.3) | Missense Mutation (SNP) | VAF 86/430 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, varscan2
- TBP | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 281/600 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, varscan2
- TEKT4 | c.287A>G p.Q96R | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.624); called by muse, varscan2
- TMEM266 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- TRIL | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, varscan2
- TRMT1 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 111/206 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); called by muse, varscan2
- TTC39C | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 53/284 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, varscan2
- ACTR1B | c.879G>A p.T293= | Silent (SNP) | VAF 151/357 reads (42%) | catalogued as rs766871606; called by muse, varscan2
- ADAM2 | c.1557T>G p.T519= | Silent (SNP) | VAF 236/630 reads (37%) | called by muse, varscan2
- ADAMTSL4 | c.1641C>T p.S547= | Silent (SNP) | VAF 62/260 reads (24%) | called by muse, varscan2
- ADAT2 | c.231C>T p.I77= | Silent (SNP) | VAF 209/509 reads (41%) | catalogued as rs779333821, COSV52794889; called by muse, varscan2
- AGBL1 | c.765C>T p.P255= | Silent (SNP) | VAF 171/328 reads (52%) | catalogued as rs375624311, COSV101408295; called by muse, varscan2
- ANO8 | c.1656G>A p.A552= | Silent (SNP) | VAF 64/183 reads (35%) | called by muse, varscan2
- APC2 | c.2661C>T p.G887= | Silent (SNP) | VAF 44/48 reads (92%) | catalogued as rs1301505394; called by muse, varscan2
- ARRDC4 | c.1233C>T p.S411= | Silent (SNP) | VAF 164/451 reads (36%) | called by muse, varscan2
- ASMTL | c.1320G>A p.A440= | Silent (SNP) | VAF 89/158 reads (56%) | catalogued as rs748809397; called by muse, varscan2
- ATM | c.3999T>C p.D1333= | Silent (SNP) | VAF 248/281 reads (88%) | called by muse, varscan2
- ATP13A3 | c.639C>T p.N213= | Silent (SNP) | VAF 186/523 reads (36%) | called by muse, varscan2
- B3GNT8 | c.309C>T p.T103= | Silent (SNP) | VAF 14/136 reads (10%) | catalogued as rs764666731, COSV54196544; called by muse, varscan2
- B4GALNT3 | c.2613G>A p.P871= | Silent (SNP) | VAF 38/224 reads (17%) | catalogued as rs760374578, COSV56751923; called by muse, varscan2
- BCAT2 | c.537G>A p.S179= | Silent (SNP) | VAF 44/188 reads (23%) | called by muse, varscan2
- BSND | c.102C>T p.Y34= | Silent (SNP) | VAF 186/356 reads (52%) | catalogued as rs141403253; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely benign; called by muse, varscan2
- C2CD4D | c.876C>T p.F292= | Silent (SNP) | VAF 103/202 reads (51%) | catalogued as COSV63256293; called by muse, varscan2
- CAMK2B | c.570G>A p.A190= | Silent (SNP) | VAF 172/382 reads (45%) | catalogued as rs141891199; called by muse, varscan2
- CAMKK2 | c.42C>T p.A14= | Silent (SNP) | VAF 66/185 reads (36%) | catalogued as rs200559115; called by muse, varscan2
- CAPN10 | c.1797G>A p.P599= | Silent (SNP) | VAF 82/192 reads (43%) | called by muse, varscan2
- CBLC | c.396C>T p.H132= | Silent (SNP) | VAF 112/178 reads (63%) | catalogued as rs199680893, COSV54324545; called by muse, varscan2
- CCDC110 | c.498C>T p.S166= | Silent (SNP) | VAF 158/361 reads (44%) | catalogued as rs761432896, COSV56871458; called by muse, varscan2
- CDH23 | c.534C>T p.F178= | Silent (SNP) | VAF 122/286 reads (43%) | catalogued as rs545549662; called by muse, varscan2
- CDKN2AIP | c.450C>T p.N150= | Silent (SNP) | VAF 234/474 reads (49%) | called by muse, varscan2
- CELSR1 | c.3600C>T p.D1200= | Silent (SNP) | VAF 124/328 reads (38%) | catalogued as rs773471661, COSV53088490; called by muse, varscan2
- CELSR3 | c.1386G>A p.A462= | Silent (SNP) | VAF 78/170 reads (46%) | called by muse, varscan2
- CEND1 | c.405C>A p.A135= | Silent (SNP) | VAF 78/226 reads (35%) | called by muse, varscan2
- CENPE | c.3576T>C p.Y1192= | Silent (SNP) | VAF 68/512 reads (13%) | called by muse, varscan2
- CEP131 | c.1944C>T p.C648= (on ENST00000269392 / NM_001319228.2; = p.C645= on NM_014984.4) | Silent (SNP) | VAF 170/349 reads (49%) | catalogued as rs368017972; called by muse, varscan2
- CERS6 | c.192C>A p.A64= | Silent (SNP) | VAF 167/419 reads (40%) | called by muse, varscan2
- CHDH | c.636G>A p.P212= | Silent (SNP) | VAF 164/356 reads (46%) | catalogued as rs749066657, COSV59458676; called by muse, varscan2
- CLIC6 | c.1503C>T p.G501= (on ENST00000360731 / NM_001317009.2; = p.G483= on NM_053277.3) | Silent (SNP) | VAF 70/352 reads (20%) | catalogued as rs369846247; called by muse, varscan2
- CMTM2 | c.456C>T p.N152= | Silent (SNP) | VAF 140/283 reads (49%) | catalogued as rs1044981725, COSV51748336; called by muse, varscan2
- CPTP | c.303G>A p.P101= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as rs760362777; called by muse, varscan2
- CYHR1 | c.567C>T p.C189= | Silent (SNP) | VAF 91/326 reads (28%) | catalogued as rs372200827; called by muse, varscan2
- CYP1A1 | c.1317C>T p.I439= | Silent (SNP) | VAF 129/376 reads (34%) | catalogued as rs200091037, COSV101122343; called by muse, varscan2
- CYP3A4 | c.1590C>T p.T530= (on ENST00000336411; = p.T499= on NM_017460.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 90/416 reads (22%) | catalogued as rs147125009, COSV60503576; called by muse, varscan2
- DHX32 | c.393G>A p.A131= | Silent (SNP) | VAF 168/373 reads (45%) | catalogued as rs140829022; called by muse, varscan2
- DLG5 | c.1815C>T p.H605= | Silent (SNP) | VAF 206/424 reads (49%) | catalogued as rs370703846; called by muse, varscan2
- DNASE1 | c.378C>T p.C126= | Silent (SNP) | VAF 136/246 reads (55%) | catalogued as rs780408465; called by muse, varscan2
- EFCAB6 | c.2622C>T p.N874= | Silent (SNP) | VAF 216/440 reads (49%) | catalogued as rs769032094, COSV53061732; called by muse, varscan2
- EGF | c.69G>A p.P23= | Silent (SNP) | VAF 170/354 reads (48%) | catalogued as rs750103075, COSV54477053; called by muse, varscan2
- EIF2A | c.195T>C p.T65= | Silent (SNP) | VAF 214/453 reads (47%) | called by muse, varscan2
- ENPEP | c.147C>T p.G49= | Silent (SNP) | VAF 100/176 reads (57%) | catalogued as rs775120757, COSV54450020; called by muse, varscan2
- EPHX1 | c.165G>A p.T55= | Silent (SNP) | VAF 198/450 reads (44%) | catalogued as rs182154631; called by muse, varscan2
- EPPK1 | c.6756C>T p.G2252= | Silent (SNP) | VAF 41/257 reads (16%) | catalogued as rs1184324579; called by muse, varscan2
- FAM13B | c.237C>T p.S79= | Silent (SNP) | VAF 30/278 reads (11%) | catalogued as rs577280714, COSV50366377; called by muse, varscan2
- FAM47C | c.168C>T p.D56= | Silent (SNP) | VAF 129/143 reads (90%) | catalogued as rs1378928507, COSV100792242; called by muse, varscan2
- FASTKD3 | c.993C>T p.N331= | Silent (SNP) | VAF 208/536 reads (39%) | catalogued as rs759461629, COSV99241318; called by muse, varscan2
- FBLL1 | c.756G>A p.P252= | Silent (SNP) | VAF 170/182 reads (93%) | catalogued as rs1181266431; called by muse, varscan2
- FBP2 | c.306C>T p.D102= | Silent (SNP) | VAF 176/276 reads (64%) | catalogued as rs746957973, COSV64696215; called by muse, varscan2
- FGFR3 | c.312C>T p.S104= | Silent (SNP) | VAF 67/77 reads (87%) | catalogued as rs377018654; ClinVar: likely benign; called by muse, varscan2
- FGFR3 | c.792G>A p.T264= | Silent (SNP) | VAF 128/148 reads (86%) | catalogued as rs754400359; ClinVar: likely benign; called by muse, varscan2
- FHOD3 | c.711G>A p.T237= | Silent (SNP) | VAF 82/355 reads (23%) | catalogued as rs753187423, COSV57169797; called by muse, varscan2
- GARRE1 | c.975G>A p.T325= | Silent (SNP) | VAF 98/286 reads (34%) | catalogued as rs753180321, COSV55105923; called by muse, varscan2
- GASK1A | c.1326C>T p.F442= | Silent (SNP) | VAF 182/445 reads (41%) | catalogued as rs1467900399; called by muse, varscan2
- GET1 | c.126C>T p.D42= | Silent (SNP) | VAF 46/174 reads (26%) | catalogued as rs764085148, COSV61554788; called by muse, varscan2
- GGT7 | c.1701G>A p.A567= | Silent (SNP) | VAF 129/295 reads (44%) | catalogued as rs780921464, COSV60540710; called by muse, varscan2
- GMEB2 | c.936C>T p.Y312= | Silent (SNP) | VAF 80/196 reads (41%) | catalogued as rs145663342; called by muse, varscan2
- GNA11 | c.309C>T p.Y103= | Silent (SNP) | VAF 149/165 reads (90%) | catalogued as rs758603549, COSV99313089; called by muse, varscan2
- GOLGA3 | c.4362C>T p.H1454= | Silent (SNP) | VAF 120/228 reads (53%) | catalogued as rs772802956; called by muse, varscan2
- GPIHBP1 | c.495C>T p.G165= | Silent (SNP) | VAF 79/180 reads (44%) | catalogued as rs756979938, COSV58209004; called by muse, varscan2
- GPR12 | c.432C>T p.Y144= | Silent (SNP) | VAF 134/453 reads (30%) | catalogued as COSV67344643; called by muse, varscan2
- GPR137 | c.441G>A p.S147= | Silent (SNP) | VAF 57/139 reads (41%) | catalogued as rs778565162; called by muse, varscan2
- GPR146 | c.795C>T p.P265= | Silent (SNP) | VAF 88/200 reads (44%) | catalogued as rs913828542, COSV99866097; called by muse, varscan2
- GPR75 | c.957C>T p.A319= | Silent (SNP) | VAF 158/282 reads (56%) | catalogued as rs750837816; called by muse, varscan2
- GPRC5C | c.312G>A p.A104= (on ENST00000652232; = p.A59= on NM_018653.4) | Silent (SNP) | VAF 74/204 reads (36%) | catalogued as rs1208558799, COSV61238822; called by muse, varscan2
- GRIN2D | c.1224G>A p.T408= | Silent (SNP) | VAF 107/151 reads (71%) | catalogued as rs1398277352; called by muse, varscan2
- GRIP2 | c.840C>T p.P280= (on ENST00000619221; = p.P183= on NM_001080423.4) | Silent (SNP) | VAF 111/265 reads (42%) | catalogued as rs770772184; called by muse, varscan2
- HCAR3 | c.783G>A p.S261= | Silent (SNP) | VAF 23/122 reads (19%) | catalogued as rs778187513; called by muse, varscan2
- HELZ2 | c.5319C>T p.Y1773= (on ENST00000467148 / NM_001037335.2; = p.Y1204= on NM_033405.3) | Silent (SNP) | VAF 58/107 reads (54%) | catalogued as rs528250359; called by muse, varscan2
- HERC2 | c.12489C>T p.D4163= | Silent (SNP) | VAF 158/273 reads (58%) | catalogued as rs752941725; called by muse, varscan2
- HYKK | c.414C>T p.P138= | Silent (SNP) | VAF 124/424 reads (29%) | catalogued as rs767946770; called by muse, varscan2
- IFT140 | c.882C>T p.A294= | Silent (SNP) | VAF 95/286 reads (33%) | catalogued as rs768675467; called by muse, varscan2
- IGFALS | c.714C>T p.F238= | Silent (SNP) | VAF 68/112 reads (61%) | catalogued as rs759989529, COSV51907444; called by muse, varscan2
- IGSF6 | c.510C>T p.C170= | Silent (SNP) | VAF 100/352 reads (28%) | catalogued as rs183946841, COSV99193630; called by muse, varscan2
- ILDR1 | c.1491C>T p.R497= (on ENST00000344209 / NM_001199799.2; = p.R453= on NM_175924.4) | Silent (SNP) | VAF 148/342 reads (43%) | catalogued as rs367565247; called by muse, varscan2
- INTS1 | c.3585G>A p.P1195= | Silent (SNP) | VAF 146/347 reads (42%) | catalogued as rs371444064; called by muse, varscan2
- IQCM | c.1380T>C p.Y460= | Silent (SNP) | VAF 163/322 reads (51%) | called by muse, varscan2
- JCAD | c.3888C>T p.A1296= | Silent (SNP) | VAF 116/218 reads (53%) | catalogued as rs780795454; called by muse, varscan2
- KALRN | c.3342C>T p.R1114= | Silent (SNP) | VAF 168/457 reads (37%) | catalogued as rs140963587; called by muse, varscan2
- KBTBD6 | c.1110G>A p.P370= | Silent (SNP) | VAF 68/198 reads (34%) | catalogued as rs767458312; called by muse, varscan2
- KCNC3 | c.1743G>A p.P581= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as rs746696640; called by muse, varscan2
- KCNH4 | c.804C>T p.I268= | Silent (SNP) | VAF 140/357 reads (39%) | catalogued as rs1309780392, COSV52916904; called by muse, varscan2
- KCTD10 | c.315C>T p.I105= | Silent (SNP) | VAF 124/350 reads (35%) | catalogued as rs758410649, COSV57326219; called by muse, varscan2
- KDM2B | c.2088C>T p.H696= | Silent (SNP) | VAF 138/370 reads (37%) | called by muse, varscan2
- KIF13B | c.4920G>A p.P1640= | Silent (SNP) | VAF 85/235 reads (36%) | called by muse, varscan2
- KIF18A | c.2352C>T p.P784= | Silent (SNP) | VAF 158/526 reads (30%) | catalogued as rs201624190; called by muse, varscan2
- KLHL29 | c.648C>T p.S216= | Silent (SNP) | VAF 34/260 reads (13%) | catalogued as rs763965543; called by muse, varscan2
- KNTC1 | c.5298C>T p.I1766= | Silent (SNP) | VAF 161/447 reads (36%) | catalogued as rs751686054, COSV100337888; called by muse, varscan2
- LHX2 | c.741C>T p.N247= | Silent (SNP) | VAF 180/293 reads (61%) | catalogued as rs755198475, COSV65319178; called by muse, varscan2
- MAP1S | c.1128C>T p.P376= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as rs751135160; called by muse, varscan2
- MAP1S | c.2463C>T p.H821= | Silent (SNP) | VAF 76/114 reads (67%) | catalogued as rs1281069996; called by muse, varscan2
- MDH2 | c.873G>A p.P291= | Silent (SNP) | VAF 162/422 reads (38%) | catalogued as rs782097820, COSV59885440; ClinVar: likely benign; called by muse, varscan2
- MED23 | c.3624G>A p.T1208= | Silent (SNP) | VAF 312/675 reads (46%) | catalogued as rs1025453796; called by muse, varscan2
- MMRN1 | c.2301C>T p.S767= | Silent (SNP) | VAF 142/328 reads (43%) | catalogued as rs575370257; called by muse, varscan2
- MOGAT3 | c.672G>A p.A224= | Silent (SNP) | VAF 120/266 reads (45%) | catalogued as rs140645427; called by muse, varscan2
- MVD | c.756C>T p.F252= | Silent (SNP) | VAF 48/110 reads (44%) | catalogued as rs749517862; called by muse, varscan2
- MVP | c.2157C>T p.T719= | Silent (SNP) | VAF 64/155 reads (41%) | catalogued as rs145541123; called by muse, varscan2
- MYH11 | c.3999C>T p.N1333= | Silent (SNP) | VAF 154/293 reads (53%) | catalogued as rs768465413, COSV55565209; ClinVar: likely benign; called by muse, varscan2
- MYH7 | c.3474C>T p.S1158= | Silent (SNP) | VAF 92/271 reads (34%) | catalogued as rs587780395; ClinVar: likely benign / uncertain significance / benign; called by muse, varscan2
- MYO10 | c.3309C>T p.S1103= | Silent (SNP) | VAF 147/247 reads (60%) | catalogued as rs376020827; called by muse, varscan2
- MYO15A | c.396G>A p.T132= | Silent (SNP) | VAF 30/280 reads (11%) | catalogued as rs1325831346, COSV52759930; called by muse, varscan2
- MYORG | c.1287C>T p.I429= | Silent (SNP) | VAF 114/135 reads (84%) | catalogued as rs1459496100; called by muse, varscan2
- NAT16 | c.693C>T p.S231= | Silent (SNP) | VAF 94/186 reads (51%) | called by muse, varscan2
- NAV2 | c.7056C>T p.D2352= (on ENST00000396087 / NM_001244963.2; = p.D2293= on NM_145117.5) | Silent (SNP) | VAF 116/372 reads (31%) | catalogued as rs368500913; called by muse, varscan2
- NBEAL2 | c.5124C>T p.P1708= | Silent (SNP) | VAF 175/422 reads (41%) | catalogued as rs371275683; called by muse, varscan2
- NDST3 | c.1830T>G p.A610= | Silent (SNP) | VAF 34/312 reads (11%) | called by muse, varscan2
- NEB | c.17868G>A p.T5956= | Silent (SNP) | VAF 205/507 reads (40%) | catalogued as rs750627350, COSV51446131; called by muse, varscan2
- NEDD4L | c.2334C>T p.D778= (on ENST00000400345 / NM_001144967.3; = p.D758= on NM_015277.6) | Silent (SNP) | VAF 294/482 reads (61%) | catalogued as rs200245819; ClinVar: likely benign; called by muse, varscan2
- NF1 | c.2658C>T p.N886= | Silent (SNP) | VAF 253/567 reads (45%) | catalogued as rs781549970; ClinVar: likely benign; called by muse, varscan2
- NFASC | c.1236C>T p.N412= (on ENST00000339876 / NM_001378329.1; = p.N423= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 234/450 reads (52%) | catalogued as COSV58361616; called by muse, varscan2
- NKPD1 | c.780G>A p.L260= | Silent (SNP) | VAF 26/76 reads (34%) | called by muse, varscan2
- OR2A1 | c.294G>A p.T98= | Silent (SNP) | VAF 142/416 reads (34%) | catalogued as rs372281270; called by muse, varscan2
- P2RY2 | c.939C>T p.L313= | Silent (SNP) | VAF 126/231 reads (55%) | catalogued as rs182109065; called by muse, varscan2
- PANK4 | c.837G>A p.S279= | Silent (SNP) | VAF 156/358 reads (44%) | catalogued as rs758722675; called by muse, varscan2
- PAX6 | c.285G>A p.P95= | Silent (SNP) | VAF 166/282 reads (59%) | catalogued as rs571551224, COSV53793215; called by muse, varscan2
- PCDH15 | c.1605C>T p.D535= | Silent (SNP) | VAF 238/534 reads (45%) | catalogued as rs370348265, COSV57271337; ClinVar: likely benign; called by muse, varscan2
- PCF11 | c.1167G>A p.S389= | Silent (SNP) | VAF 116/896 reads (13%) | catalogued as rs753901279; called by muse, varscan2
- PDZRN3 | c.1068G>A p.T356= | Silent (SNP) | VAF 191/431 reads (44%) | catalogued as rs199688323; called by muse, varscan2
- PLEKHH3 | c.1110G>A p.A370= | Silent (SNP) | VAF 178/388 reads (46%) | catalogued as rs200157415, COSV99257808; called by muse, varscan2
- POC1A | c.465C>T p.P155= | Silent (SNP) | VAF 188/464 reads (41%) | catalogued as rs375164245; called by muse, varscan2
- PPP2R1A | c.1470C>T p.S490= | Silent (SNP) | VAF 186/272 reads (68%) | catalogued as rs187141962, COSV59046173; called by muse, varscan2
- PRAG1 | c.2046G>A p.G682= | Silent (SNP) | VAF 154/293 reads (53%) | called by muse, varscan2
- PRDM15 | c.3528C>T p.D1176= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as rs778382718; called by muse, varscan2
- PRKX | c.321G>A p.P107= | Silent (SNP) | VAF 77/87 reads (89%) | catalogued as rs1476334704, COSV99467756; called by muse, varscan2
- PRPF6 | c.1737C>T p.R579= | Silent (SNP) | VAF 142/322 reads (44%) | catalogued as rs200043606; called by muse, varscan2
- PTPRH | c.213C>T p.G71= | Silent (SNP) | VAF 48/152 reads (32%) | catalogued as rs778157024; called by muse, varscan2
- RAB3IL1 | c.345G>A p.T115= | Silent (SNP) | VAF 197/333 reads (59%) | catalogued as rs375845758; called by muse, varscan2
- RBFA | c.597C>T p.V199= | Silent (SNP) | VAF 246/403 reads (61%) | catalogued as rs192937311; called by muse, varscan2
- RBM27 | c.420C>T p.D140= | Silent (SNP) | VAF 276/294 reads (94%) | catalogued as rs549958493, COSV54590664; called by muse, varscan2
- RBM27 | c.1125C>T p.S375= | Silent (SNP) | VAF 100/120 reads (83%) | catalogued as rs770571282; called by muse, varscan2
- RIMS2 | c.2922C>T p.T974= (on ENST00000666250 / NM_001348490.2; = p.T782= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 214/442 reads (48%) | catalogued as rs765015367, COSV51671152; called by muse, varscan2
- ROCK2 | c.1518G>A p.A506= | Silent (SNP) | VAF 264/641 reads (41%) | catalogued as rs753996403, COSV55076006; called by muse, varscan2
- RRP1B | c.1395C>A p.A465= | Silent (SNP) | VAF 34/156 reads (22%) | called by muse, varscan2
- RTL1 | c.2034C>T p.N678= | Silent (SNP) | VAF 132/222 reads (59%) | catalogued as rs1314230092, COSV101128110; called by muse, varscan2
- SALL3 | c.2289C>T p.G763= | Silent (SNP) | VAF 88/314 reads (28%) | catalogued as rs751203516, COSV73305763; called by muse, varscan2
- SBF1 | c.2517G>A p.T839= | Silent (SNP) | VAF 139/263 reads (53%) | catalogued as rs781298363; called by muse, varscan2
- SCN3A | c.1842G>A p.P614= | Silent (SNP) | VAF 246/594 reads (41%) | catalogued as rs370922010; ClinVar: likely benign; called by muse, varscan2
- SHANK2 | c.3189G>A p.P1063= | Silent (SNP) | VAF 238/424 reads (56%) | catalogued as rs1381402576; called by muse, varscan2
- SLAMF1 | c.678C>T p.P226= | Silent (SNP) | VAF 205/413 reads (50%) | catalogued as rs200678007, COSV52498372; called by muse, varscan2
- SLC15A5 | c.87C>T p.G29= | Silent (SNP) | VAF 207/232 reads (89%) | catalogued as rs776441301; called by muse, varscan2
- SLC2A7 | c.972G>A p.T324= | Silent (SNP) | VAF 137/405 reads (34%) | catalogued as rs113762316, COSV68902116; called by muse, varscan2
- SLC30A8 | c.561G>A p.A187= | Silent (SNP) | VAF 168/332 reads (51%) | catalogued as rs755241418, COSV69975799; called by muse, varscan2
- SLC35D3 | c.567G>A p.A189= | Silent (SNP) | VAF 102/199 reads (51%) | called by muse, varscan2
- SLC4A10 | c.1611G>A p.G537= (on ENST00000446997 / NM_001354461.2; = p.G507= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 172/396 reads (43%) | called by muse, varscan2
- SLCO3A1 | c.357C>T p.G119= | Silent (SNP) | VAF 67/116 reads (58%) | catalogued as rs765260047, COSV59236091; called by muse, varscan2
- SLITRK1 | c.1359C>T p.N453= | Silent (SNP) | VAF 181/205 reads (88%) | catalogued as COSV65677365; called by muse, varscan2
- SPATA31D4 | c.2235C>T p.S745= | Silent (SNP) | VAF 236/730 reads (32%) | catalogued as rs761740169; called by muse, varscan2
- SPECC1 | c.2361T>C p.D787= | Silent (SNP) | VAF 138/524 reads (26%) | catalogued as rs902817261; called by muse, varscan2
- SRCAP | c.7131C>T p.G2377= | Silent (SNP) | VAF 18/157 reads (11%) | catalogued as rs775810288; called by muse, varscan2
- SSC5D | c.1197C>T p.A399= | Silent (SNP) | VAF 54/154 reads (35%) | called by muse, varscan2
- SSTR5 | c.159C>T p.A53= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as rs376300888; called by muse, varscan2
- STXBP5L | c.3381C>T p.G1127= | Silent (SNP) | VAF 120/632 reads (19%) | catalogued as rs755646794, COSV56516467, COSV56537923; called by muse, varscan2
- TADA1 | c.822G>A p.P274= | Silent (SNP) | VAF 313/794 reads (39%) | catalogued as rs541297164; called by muse, varscan2
- TAOK3 | c.1152C>T p.D384= | Silent (SNP) | VAF 246/430 reads (57%) | catalogued as rs778284750, COSV66825572; called by muse, varscan2
- TEFM | c.297C>T p.I99= | Silent (SNP) | VAF 171/706 reads (24%) | catalogued as rs377501758; called by muse, varscan2
- TENT4B | c.1716G>A p.S572= (on ENST00000561678 / NM_001365323.2; = p.S557= on NM_001040284.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 94/287 reads (33%) | catalogued as rs781627663; called by muse, varscan2
- TEX2 | c.1350G>A p.A450= | Silent (SNP) | VAF 114/274 reads (42%) | catalogued as rs142804034, COSV99366971; called by muse, varscan2
- TINAGL1 | c.129G>A p.A43= | Silent (SNP) | VAF 90/154 reads (58%) | catalogued as rs201831595; called by muse, varscan2
- TMEM160 | c.348G>A p.S116= | Silent (SNP) | VAF 55/187 reads (29%) | catalogued as rs779702999; called by muse, varscan2
- TMEM161A | c.1239C>A p.S413= | Silent (SNP) | VAF 70/259 reads (27%) | called by muse, varscan2
- TONSL | c.1455C>T p.A485= | Silent (SNP) | VAF 136/289 reads (47%) | catalogued as rs570770510, COSV68047519, COSV68047579; called by muse, varscan2
- TOX2 | c.528C>T p.H176= (on ENST00000358131 / NM_001098798.2; = p.H125= on NM_032883.3) | Silent (SNP) | VAF 124/382 reads (32%) | called by muse, varscan2
- TRAK1 | c.2511C>T p.S837= | Silent (SNP) | VAF 147/323 reads (46%) | catalogued as rs377344183; called by muse, varscan2
- TRIM22 | c.402C>T p.N134= | Silent (SNP) | VAF 134/412 reads (33%) | catalogued as rs775242351; called by muse, varscan2
- TTC21A | c.3540G>A p.A1180= | Silent (SNP) | VAF 165/391 reads (42%) | catalogued as rs371534424; called by muse, varscan2
- TTLL6 | c.1908G>A p.A636= (on ENST00000393382 / NM_001130918.3; = p.A329= on NM_173623.3) | Silent (SNP) | VAF 135/263 reads (51%) | catalogued as rs148851328, COSV64979580; called by muse, varscan2
- TUBGCP6 | c.5190G>A p.A1730= | Silent (SNP) | VAF 117/246 reads (48%) | catalogued as rs761723287; called by muse, varscan2
- TXNIP | c.741C>T p.C247= | Silent (SNP) | VAF 234/462 reads (51%) | catalogued as rs782785376; called by muse, varscan2
- USH1C | c.375C>T p.S125= | Silent (SNP) | VAF 144/288 reads (50%) | catalogued as rs1007641421, COSV50014771; called by muse, varscan2
- ZC3H4 | c.525G>A p.T175= | Silent (SNP) | VAF 193/315 reads (61%) | catalogued as rs565152158, COSV99451776; called by muse, varscan2
- ZNF236 | c.3006C>T p.R1002= | Silent (SNP) | VAF 128/620 reads (21%) | catalogued as rs779572638; called by muse, varscan2
- ZNF334 | c.624G>A p.P208= | Silent (SNP) | VAF 288/620 reads (46%) | catalogued as rs548225062, COSV61618602; called by muse, varscan2
- ZNF454 | c.39G>A p.S13= | Silent (SNP) | VAF 224/247 reads (91%) | catalogued as rs770644793, COSV100194756; called by muse, varscan2
- ZNF497 | c.195C>T p.D65= | Silent (SNP) | VAF 40/64 reads (63%) | catalogued as rs752982871; called by muse, varscan2
- ZNF536 | c.600C>T p.H200= | Silent (SNP) | VAF 106/170 reads (62%) | catalogued as COSV100834500; called by muse, varscan2
- ZNF787 | c.543G>A p.P181= | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as COSV54417767; called by muse, varscan2
- ZNF862 | c.2757G>A p.A919= | Silent (SNP) | VAF 76/352 reads (22%) | catalogued as rs754832160; called by muse, varscan2
- ZZEF1 | c.8223C>T p.D2741= | Silent (SNP) | VAF 214/469 reads (46%) | catalogued as rs371711530; called by muse, varscan2
- ACACB | c.*31C>T | 3'UTR (SNP) | VAF 32/88 reads (36%) | catalogued as rs199620387; called by muse, varscan2
- ADAMTS3 | c.862-83T>G | Intron (SNP) | VAF 56/119 reads (47%) | called by muse, varscan2
- ADCY1 | c.1605+2141C>T | Intron (SNP) | VAF 130/284 reads (46%) | catalogued as rs570388484; called by muse, varscan2
- ANKRD11 | c.-59-7200C>T | Intron (SNP) | VAF 94/210 reads (45%) | called by muse, varscan2
- ASB7 | c.-41G>A | 5'UTR (SNP) | VAF 50/159 reads (31%) | catalogued as rs371820144; called by muse, varscan2
- BCL7B | c.266-35G>A | Intron (SNP) | VAF 126/299 reads (42%) | catalogued as rs782648092; called by muse, varscan2
- BIRC5 | c.222-48G>A | Intron (SNP) | VAF 45/98 reads (46%) | catalogued as rs367598501; called by muse, varscan2
- BSG | c.572+25G>A | Intron (SNP) | VAF 138/158 reads (87%) | catalogued as rs368943609; called by muse, varscan2
- C12orf40 | c.-61C>T | 5'UTR (SNP) | VAF 146/250 reads (58%) | called by muse, varscan2
- C19orf67 | c.-42C>T | 5'UTR (SNP) | VAF 6/34 reads (18%) | called by muse, varscan2
- C3 | c.4850+18G>A | Intron (SNP) | VAF 112/126 reads (89%) | called by muse, varscan2
- C9orf106 | n.48C>T | RNA (SNP) | VAF 32/105 reads (30%) | catalogued as rs571547401; called by muse, varscan2
- CABP2 | c.*18A>C | 3'UTR (SNP) | VAF 80/234 reads (34%) | called by muse, varscan2
- CATSPER4 | c.1365+33C>T | Intron (SNP) | VAF 62/112 reads (55%) | called by muse, varscan2
- CBR1 | c.397+22G>A | Intron (SNP) | VAF 110/180 reads (61%) | catalogued as rs757494065, COSV99289410; called by muse, varscan2
- CENPT | c.704-68C>T | Intron (SNP) | VAF 22/42 reads (52%) | catalogued as rs977687473; called by muse, varscan2
- CFAP91 | c.1680+96G>A | Intron (SNP) | VAF 96/157 reads (61%) | called by muse, varscan2
- CFB | c.485-20G>A | Intron (SNP) | VAF 141/167 reads (84%) | catalogued as rs536702679; called by muse, varscan2
- CHD6 | c.975-20A>G | Intron (SNP) | VAF 140/334 reads (42%) | called by muse, varscan2
- CHMP4B | c.*45C>T | 3'UTR (SNP) | VAF 101/221 reads (46%) | catalogued as rs1052212073, COSV54136147; called by muse, varscan2
- CPEB1-AS1 | chr15:82647871 G>T | 5'Flank (SNP) | VAF 57/106 reads (54%) | called by muse, varscan2
- CRB1 | c.3878+99C>A | Intron (SNP) | VAF 36/134 reads (27%) | catalogued as COSV100957602; called by muse, varscan2
- CSK | c.129+13C>T | Intron (SNP) | VAF 56/119 reads (47%) | catalogued as rs763202217; called by muse, varscan2
- DCAF15 | c.1311+37G>A | Intron (SNP) | VAF 78/119 reads (66%) | catalogued as rs546524372; called by muse, varscan2
- DDB2 | c.456+63G>A | Intron (SNP) | VAF 40/154 reads (26%) | catalogued as rs4647711; called by muse, varscan2
- DELEC1 | n.572C>A | RNA (SNP) | VAF 129/425 reads (30%) | called by muse, varscan2
- DHFR2 | c.-92C>T | 5'UTR (SNP) | VAF 26/58 reads (45%) | catalogued as COSV100113393; called by muse, varscan2
- DIRAS2 | c.-32G>A | 5'UTR (SNP) | VAF 33/160 reads (21%) | catalogued as rs779081425, COSV101005811; called by muse, varscan2
- DNAH14 | c.5584+5625C>T | Intron (SNP) | VAF 303/720 reads (42%) | catalogued as rs370676245; called by muse, varscan2
- DPH1 | c.62-88C>T | Intron (SNP) | VAF 71/140 reads (51%) | catalogued as rs547431449; called by muse, varscan2
- DUS3L | c.1389+65T>C | Intron (SNP) | VAF 30/34 reads (88%) | catalogued as rs537599583; called by muse, varscan2
- EFNA2 | c.*79C>T | 3'UTR (SNP) | VAF 20/23 reads (87%) | called by muse, varscan2
- FAM114A1 | c.1537-2403G>A | Intron (SNP) | VAF 156/174 reads (90%) | catalogued as rs1046705113; called by muse, varscan2
- FAM157A | n.269T>C | RNA (SNP) | VAF 46/213 reads (22%) | catalogued as rs542355751; called by muse, varscan2
- FAM187B | c.*4G>A | 3'UTR (SNP) | VAF 27/97 reads (28%) | catalogued as rs773386527; called by muse, varscan2
- FAM86C1P | n.284+75T>A | Intron (SNP) | VAF 62/106 reads (58%) | called by muse, varscan2
- FRMD1 | c.462-34G>A | Intron (SNP) | VAF 41/91 reads (45%) | called by muse, varscan2
- GMPPB | c.952-18G>A | Intron (SNP) | VAF 68/152 reads (45%) | called by muse, varscan2
- GSTM2 | c.260-9C>T | Intron (SNP) | VAF 144/269 reads (54%) | catalogued as rs749281284; called by muse, varscan2
- GTPBP8 | chr3:112990918 G>A | 5'Flank (SNP) | VAF 45/106 reads (42%) | called by muse, varscan2
- HAL | c.248-14G>A | Intron (SNP) | VAF 109/202 reads (54%) | catalogued as rs751044169; called by muse, varscan2
- HTT | c.1273+84C>G | Intron (SNP) | VAF 70/74 reads (95%) | called by muse, varscan2
- ICA1 | c.1331-31C>T | Intron (SNP) | VAF 49/105 reads (47%) | catalogued as rs374438830; called by muse, varscan2
- IGSF9B | c.410-87G>A | Intron (SNP) | VAF 34/42 reads (81%) | called by muse, varscan2
- IL19 | c.-80C>T | 5'UTR (SNP) | VAF 263/485 reads (54%) | catalogued as rs754089269; called by muse, varscan2
- JAKMIP3 | c.*288G>A | 3'UTR (SNP) | VAF 74/152 reads (49%) | catalogued as rs779013303; called by muse, varscan2
- KCNJ18 | c.*37C>T | 3'UTR (SNP) | VAF 50/144 reads (35%) | catalogued as rs1189584788; called by muse, varscan2
- KCNQ2 | c.1247+72C>T | Intron (SNP) | VAF 68/142 reads (48%) | catalogued as rs1417263244; called by muse, varscan2
- KIAA0930 | c.*3G>A | 3'UTR (SNP) | VAF 138/264 reads (52%) | catalogued as rs767156891, COSV99325887; called by muse, varscan2
- KIF25 | c.93-48C>T | Intron (SNP) | VAF 145/334 reads (43%) | catalogued as rs750056333; called by muse, varscan2
- LGALS9 | c.759-36C>T | Intron (SNP) | VAF 103/236 reads (44%) | catalogued as rs1228801488; called by muse, varscan2
- LRRC37A2 | c.2906+4972G>A | Intron (SNP) | VAF 80/425 reads (19%) | catalogued as rs1345730235; called by muse, varscan2
- LTBP4 | chr19:40593077 G>A | 5'Flank (SNP) | VAF 20/73 reads (27%) | called by muse, varscan2
- LZTS2 | c.408+9C>T | Intron (SNP) | VAF 96/296 reads (32%) | catalogued as rs368952725; called by muse, varscan2
- MBOAT7 | c.*48C>G | 3'UTR (SNP) | VAF 88/126 reads (70%) | called by muse, varscan2
- MFSD4A | c.1369-45G>A | Intron (SNP) | VAF 70/352 reads (20%) | catalogued as rs549465212; called by muse, varscan2
- MUC4 | c.15329-32C>T | Intron (SNP) | VAF 40/104 reads (38%) | catalogued as rs376643928; called by muse, varscan2
- MYT1L | c.3271-19G>A | Intron (SNP) | VAF 94/234 reads (40%) | catalogued as rs754873838; called by muse, varscan2
- NCOA1 | c.2599+33G>A | Intron (SNP) | VAF 104/204 reads (51%) | catalogued as rs750471113; called by muse, varscan2
- NETO1 | c.469+23548G>A | Intron (SNP) | VAF 300/704 reads (43%) | catalogued as rs757059959, COSV100197955; called by muse, varscan2
- NPAS2 | c.1392+28C>T | Intron (SNP) | VAF 70/145 reads (48%) | catalogued as rs373094333; called by muse, varscan2
- NRBF2P6 | n.224G>A | RNA (SNP) | VAF 120/248 reads (48%) | called by muse, varscan2
- OBSCN | c.18662-2303G>A | Intron (SNP) | VAF 88/342 reads (26%) | catalogued as rs1322574407, COSV52772737; called by muse, varscan2
- OLA1 | c.*82C>T | 3'UTR (SNP) | VAF 58/138 reads (42%) | catalogued as rs556506955; called by muse, varscan2
- OSR1 | c.-32-60C>T | Intron (SNP) | VAF 8/18 reads (44%) | called by muse, varscan2
- OXR1 | c.-70G>A | 5'UTR (SNP) | VAF 55/283 reads (19%) | catalogued as rs1055591867; called by muse, varscan2
- PARG | c.*43C>T | 3'UTR (SNP) | VAF 102/208 reads (49%) | catalogued as rs1341235217, COSV101312627; called by muse, varscan2
- PARP3 | c.502-45C>T | Intron (SNP) | VAF 95/233 reads (41%) | catalogued as rs373356927; called by muse, varscan2
- PDHB | c.935-47G>A | Intron (SNP) | VAF 52/124 reads (42%) | called by muse, varscan2
- PDZD9 | c.*8G>A | 3'UTR (SNP) | VAF 124/236 reads (53%) | called by muse, varscan2
- PHF3 | c.*6809C>T | 3'UTR (SNP) | VAF 68/150 reads (45%) | catalogued as rs564907739; called by muse, varscan2
- PIGQ | c.1417-144C>T | Intron (SNP) | VAF 47/133 reads (35%) | catalogued as rs532557084; called by muse, varscan2
- PIK3AP1 | c.-65G>A | 5'UTR (SNP) | VAF 7/62 reads (11%) | called by muse, varscan2
- PON2 | c.145+95T>C | Intron (SNP) | VAF 41/151 reads (27%) | called by muse, varscan2
- PRKACA | c.*55G>A | 3'UTR (SNP) | VAF 24/55 reads (44%) | catalogued as rs1471162281; called by muse, varscan2
- PRKACA | c.47-389G>A | Intron (SNP) | VAF 50/177 reads (28%) | catalogued as rs746536971; called by muse, varscan2
- PRPF31 | c.1073+52C>T | Intron (SNP) | VAF 16/58 reads (28%) | catalogued as rs747547806; called by muse, varscan2
- PSME3 | c.43-19C>T | Intron (SNP) | VAF 267/624 reads (43%) | called by muse, varscan2
- PTPRN | c.281-21C>T | Intron (SNP) | VAF 68/145 reads (47%) | catalogued as rs759252967; called by muse, varscan2
- RASSF4 | c.-4G>A | 5'UTR (SNP) | VAF 118/281 reads (42%) | called by muse, varscan2
- SELENOM | c.130-41C>T | Intron (SNP) | VAF 98/152 reads (64%) | catalogued as rs773854891; called by muse, varscan2
- SELENOW | c.55-9C>T | Intron (SNP) | VAF 146/232 reads (63%) | catalogued as rs368979832; called by muse, varscan2
- SMIM35 | c.8-16151G>A | Intron (SNP) | VAF 38/44 reads (86%) | called by muse, varscan2
- SNX30 | c.*17G>A | 3'UTR (SNP) | VAF 52/160 reads (33%) | catalogued as rs748558496; called by muse, varscan2
- SOHLH2 | c.-4G>A | 5'UTR (SNP) | VAF 69/263 reads (26%) | catalogued as rs904564190, COSV58522535; called by muse, varscan2
- SON | c.6657+105C>T | Intron (SNP) | VAF 88/276 reads (32%) | called by muse, varscan2
- STX16 | c.*25C>T | 3'UTR (SNP) | VAF 206/454 reads (45%) | catalogued as rs751752988, COSV100586751; called by muse, varscan2
- STXBP2 | c.246+41G>A | Intron (SNP) | VAF 73/83 reads (88%) | catalogued as rs758491390; called by muse, varscan2
- THAP2 | c.-44G>T | 5'UTR (SNP) | VAF 106/199 reads (53%) | catalogued as rs1335596638; called by muse, varscan2
- TRIO | c.5203+67C>T | Intron (SNP) | VAF 40/72 reads (56%) | catalogued as rs113265968, COSV60088211; called by muse, varscan2
- TRMT1L | c.1759+14C>T | Intron (SNP) | VAF 220/463 reads (48%) | catalogued as rs754234562, COSV100834660; called by muse, varscan2
- TSPAN5 | c.*60G>A | 3'UTR (SNP) | VAF 42/96 reads (44%) | catalogued as rs1257541381, COSV59878182; called by muse, varscan2
- TSTD3 | chr6:99531738 G>A | 3'Flank (SNP) | VAF 306/623 reads (49%) | catalogued as rs763018853; called by muse, varscan2
- TUBB8 | c.166+39C>T | Intron (SNP) | VAF 70/186 reads (38%) | catalogued as rs748150538; called by muse, varscan2
- UBXN2B | c.*46C>T | 3'UTR (SNP) | VAF 78/184 reads (42%) | catalogued as rs761779891, COSV101275573; called by muse, varscan2
- WWP2 | c.1593+66C>T | Intron (SNP) | VAF 84/183 reads (46%) | catalogued as rs1001325808; called by muse, varscan2
- ZNF135 | c.33+75G>A | Intron (SNP) | VAF 34/57 reads (60%) | catalogued as COSV100536781; called by muse, varscan2
- ZNF34 | c.*32C>T | 3'UTR (SNP) | VAF 9/84 reads (11%) | called by muse, varscan2
